Surgical pathology report (de-identified scan), TCGA case TCGA-30-1887, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1887-01A (Primary Tumor).

[page 1 of 4]
Accession Number: [REDACTED]

Report Status: Final

Type: Surgical Pathology

Specimen Type: Omentum

Procedure Date: [REDACTED]

Ordering Provider: [REDACTED]

CASE: [REDACTED]

PATIENT: [REDACTED]

Resident: [REDACTED]

Pathologist: [REDACTED]

TCGA-30-1887

PATHOLOGIC DIAGNOSIS:

SPECIMEN DESIGNATED "OMENTAL TUMOR" [REDACTED]

PAPILLARY SEROUS ADENOCARCINOMA infiltrating fibroadipose tissue (15 cm),
see
comment.

SPECIMEN DESIGNATED "RECTUS MUSCLE":

Tissue allocation only.

SPECIMEN DESIGNATED "ADDITIONAL OMENTUM":

PAPILLARY SEROUS ADENOCARCINOMA infiltrating fibroadipose tissue (12 cm).

SPECIMEN DESIGNATED "MESENTERY, TRANSVERSE COLON":

PAPILLARY SEROUS ADENOCARCINOMA infiltrating fibroadipose tissue (10 cm).
Lymphovascular invasion is present.

SPECIMEN DESIGNATED "UTERUS, RIGHT AND LEFT FALLOPIAN TUBES AND OVARIES":

Uterus (Wt: 34 g)

Cervix:

Squamous metaplasia.

Endomyometrium:

Inactive endometrium.

Intramural leiomyoma (0.8 cm)

Serosa:

PAPILLARY SEROUS ADENOCARCINOMA present as serosal implants; see
comment.

Ovaries and fallopian tubes:

Right fallopian tube:

PAPILLARY SEROUS ADENOCARCINOMA present as nodules in paratubal soft
tissue; see comment.
Paratubal cysts.

Right ovary:

PAPILLARY SEROUS ADENOCARCINOMA, moderately differentiated (multiple
nodules largest 0.2 cm) present on ovarian surface and infiltrating
paraovarian soft tissue.

Lymphovascular invasion is present.

Cortical (mesothelial) inclusion cysts

Left fallopian tube:

PAPILLARY SEROUS ADENOCARCINOMA, infiltrating paratubal soft tissue and
Focally in tubal metaplasia.

Left ovary:

PAPILLARY SEROUS ADENOCARCINOMA, moderately differentiated, (largest 0.5 cm)
present as

multiple nodules on ovarian surface and infiltrating paraovarian soft
tissue.

Lymphovascular invasion is present.

Serous adenofibroma, cortical (mesothelial) inclusion cysts.

[page 2 of 4]
SPECIMEN DESIGNATED "RECTOSIGMOID TUMOR":

Portion of colon (27cm).

PAPILLARY SEROUS ADENOCARCINOMA (13 cm), infiltrating pericolic adipose tissue.

Tumor invades through colonic serosa into muscularis propria, but not into submucosa.

Lymphovascular invasion is present.

Mucosal margins are viable and negative for tumor.

One (1) lymph node, negative for tumor.

TCGA-30-1887

SPECIMEN DESIGNATED "LEFT EXTERNAL ILIAC":

Two (2) lymph nodes, negative for tumor.

SPECIMEN DESIGNATED "BLADDER SOFT TISSUE":

PAPILLARY SEROUS ADENOCARCINOMA (5.5 cm) infiltrating fibroadipose tissue.

Comment: The distribution is consistent with a primary peritoneal carcinoma.

CLINICAL DATA:

History: Omental mass. CA125 6000.

Operation: Not provided.

Operative Findings: None given

Clinical Diagnosis: Omental mass

TISSUE SUBMITTED:

- A-1) Omental tumor
- B-2) Rectus muscle (to path for research)
- C-3) Additional omentectomy tumor tissue
- D-4) Mesentery transverse colon tumor
- E-5) Right tube and ovary
- F-6) Left tube and ovary
- G-7) Uterus and cervix
- H-8) Rectosigmoid tumor
- I-9) Left external iliac lymph node tissue
- J-10) Tumor from bladder

O.R. CONSULTATION:

SPECIMEN DESIGNATED "#1. OMENTAL TUMOR"

Poorly differentiated papillary serous carcinoma.

The senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimen(s) and rendered or confirmed the rapid diagnosis(es) related thereto.

GROSS DESCRIPTION:

The specimen is received fresh, in ten parts, each labeled with the patient's name and unit number.

Part A, labeled "#1. omental tumor", consists of a single fragment of yellow/orange adipose tissue, diffusely infiltrated by gray/white tumor

[page 3 of 4]
mass/nodule (15.5 x 5 x 3 cm overall). A representative section is submitted to [REDACTED] for special studies. A representative section is submitted as [REDACTED]

Micro A1: FSA remnant, 1 frag, [REDACTED] TCGA-30-1887
Micro A2-4: additional omental tumor, mult frags, [REDACTED]

Part B, labeled "#2. rectus muscle", consists of a single fragment of red/pink skeletal muscle (1 x 1 x 0.5 cm). It is entirely submitted to [REDACTED] for special studies.

Part C, labeled "#3. additional omentectomy tumor tissue", consists of a single fragment of yellow adipose tissue (19.5 x 6.8 x 2.2 cm), with multiple gray/tan tumor nodules. Tumor involves approximately 60% of the specimen.

Micro C1-2: omentum and tumor, mult frags, [REDACTED]

Part D, labeled "#4. mesentery transverse colon tumor", consists of multiple fragments of yellow adipose tissue (10 x 5 x 2 cm in aggregate), admixed with multiple gray/tan tumor nodules.

Micro D1-2: mesentery tumor, mult frags, [REDACTED]

Part E, labeled "#5. right tube and right ovary", consists of a salpingo-oophorectomy specimen including ovary (2.9 x 1.4 x 1.0 cm), and attached fallopian tube (4.5 x 0.5 cm) with a fimbriated end. Multiple (five) tan nodules are identified in the paraovarian fibrous tissue (0.1 cm in average dimension). No other gross mass lesions are identified.

Micro E1: ovary including paraovarian nodules, 2 frags, [REDACTED]

Micro E2-4: remainder of ovary, mult frags, [REDACTED]

Micro E5-7: right fallopian tube, mult frag, [REDACTED]

Part F, labeled "#6. left tube and ovary", consists of a salpingo-oophorectomy specimen including ovary (2.5 x 1.3 x 1.1 cm), attached fallopian tube (4.7 x 0.6 cm) with a fimbriated end and adherent fibrous tissue. On the ovarian surface are multiple tan/gray nodular projections.

Micro F1-4: left ovary, mult frags, [REDACTED]

Micro F6-8: left fallopian tube, mult frags, [REDACTED]

NOTE: MICRO F5 WAS NOT DICTATED.

Part G, labeled "#7. uterus and cervix", consists of a 34 gram hysterectomy specimen (7.8 x 5.9 x 2.2 cm). The exocervix measures 2.1 cm in diameter and has a tan/pink glistening mucosa. The cervical os measures 0.3 cm in diameter. The endocervical canal (2.2 cm in length), has a tan herringbone mucosa. The endometrial cavity (0. cm from cornu to cornu, 2.2 cm in length) has a tan/pink hemorrhagic endometrium (less than 0.1 cm in average thickness). The myometrium measures 1.3 cm in maximal thickness, and contains an intramural leiomyoma (0.8 cm). The serosa is dull and smooth. No mucosal lesions are identified.

Micro G1: anterior cervix, 1 frag, [REDACTED]

Micro G2: posterior cervix, 1 frag, [REDACTED]

Micro G3: lower uterine segment including leio, 1 frag, [REDACTED]

Micro G4: anterior endomyometrium, 1 frag, [REDACTED]

Micro G5: posterior endomyometrium, 1 frag, [REDACTED]

Part H, labeled "#8. rectosigmoid tumor", consists of an unoriented loop of colon (27 x 3 cm), twisted into a horseshoe configuration with distal loops separated by 2.5 cm of mesentery, by a confluent mass of matted gray/tan tumor nodule infiltrating the mesentery, and diffusely attached to the serosal surface. Mucosal margins consist of stapled lines (inked blue, 3.5 cm and 4.5 cm in length). The total gross extent of tumor within the mesentery is 13 x 6.5 x 2.5 cm. No gross mucosal lesions are identified.

Micro H1-2: mucosal margins, en face, mult frags, [REDACTED]

[page 4 of 4]
Micro H3-4: tumor to bowel wall, 2 frags, [REDACTED]
Micro H5-6: additional mesenteric tumor, 1 frag each, [REDACTED]

Part I, labeled "#9. left external iliac lymph node", consists of two fragments of fibroadipose tissue (1.7 cm and 2.2 cm in greatest dimension). Each fragment is bisected and entirely submitted.

Micro I1-2: left external iliac tissue, 4 frags, [REDACTED]

Part J, labeled "10 tumor from bladder", consists of a single fragment of fibroadipose tissue (5.5 x 2.5 x 1.0 cm), diffusely involved with a gray/tan firm lobulated tumor mass.

Micro J1-2: tumor and bladder, 2 frags, [REDACTED]
[REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

[REDACTED]

Source: NCI Genomic Data Commons file 296b9850-6e26-4eeb-89b9-90d4c3b3138a (TCGA-30-1887.A074363F-DD94-4193-B583-70885400FF2F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).